Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VM, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VM-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Right thyroid nodule with FNA #1 showing atypical cells with hypercellularity and FNA #2 showing suspicious for neoplasm. process.

Specimens Submitted:

1: Right lobe of thyroid and isthmus (fs)

DIAGNOSIS:

1. Right lobe of thyroid and isthmus (fs):

Tumor Type:

Papillary carcinoma, follicular variant 99% follicular variant per TSS per

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 3 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Two foci of vascular invasion present.

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

ICD-O-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, Nbs

C73.9 5-2-12

KD

[page 2 of 2]
Exhibits nodular hyperplasia
Parathyroid Glands:
Identified
One unremarkable parathyroid gland.

Comment: The nuclear features diagnostic of papillary carcinoma and the vascular invasion were not present on the frozen section slides.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section and is labeled "right lobe of thyroid and isthmus". It consists of a thyroid lobe measuring 5 x 3.5 x 2 cm and isthmus measuring 1.5 x 0.5 x 0.5 with an overall weight of 15 g. The surface is smooth. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a well-circumscribed, thinly encapsulated, tan nodule with dimension of 3 x 2.7 x 2 cm. A portion of tumor is submitted for frozen section and Remaining tissue is entirely submitted.

Summary of sections:

N - Nodule

RL - right lobe

IS - isthmus

Summary of Sections:

Part 1: Right lobe of thyroid and isthmus (fs)

Block	Sect. Site	PCs
1	FSC	1
1	IS	2
8	N	8
3	RL	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right lobe of thyroid and isthmus (fs): Hurthle cell neoplasm
Permanent diagnosis: See final report.

Source: NCI Genomic Data Commons file b0c16195-80cb-4fc0-b0a7-cc3a75a5dbce (TCGA-DJ-A3VM.2F246E42-FAA4-4E33-A22A-1F35ECC038FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).